Somatic mutation profile of tumor specimen MP2PRT-PAUDLA-TMP1-A (aliquot MP2PRT-PAUDLA-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PAUDLA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,442 days).
Specimen MP2PRT-PAUDLA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5f1c4b7-da16-449d-9b28-1ecf01efc983.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUDLA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUDLA-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/665bcc7e-f717-4189-8697-daa972106943

The open-access MAF lists 16 somatic variants for this specimen: 16 protein-altering or splice-affecting.
By variant classification: Missense Mutation 16.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 105/525 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTRT1 | c.883T>C p.Y295H | Missense Mutation (SNP) | VAF 38/524 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1388030011; called by muse, mutect2
- ADAMTS6 | c.2234T>C p.I745T | Missense Mutation (SNP) | VAF 77/355 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs1363245737; called by muse, mutect2, varscan2
- DRGX | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 111/581 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as rs1384783835, COSV65136161; called by muse, mutect2, varscan2
- MAGEB17 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 148/470 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.215); catalogued as rs1191070004; called by muse, mutect2, varscan2
- PLCZ1 | c.1819G>A p.V607I | Missense Mutation (SNP) | VAF 80/325 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751805291, COSV56856433; called by muse, mutect2, varscan2
- SDK1 | c.5951C>T p.A1984V | Missense Mutation (SNP) | VAF 123/428 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs751764333, COSV101269399, COSV67355098; called by muse, mutect2, varscan2
- SLC17A8 | c.1405G>A p.G469S | Missense Mutation (SNP) | VAF 77/377 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.581); catalogued as rs747411001, COSV60126852; called by muse, mutect2, varscan2
- USP48 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 121/495 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs964710315, COSV57609339; called by muse, mutect2, varscan2
- XYLT2 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 176/704 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764623385; called by muse, mutect2, varscan2
- CD5L | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 100/376 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DST | c.4456G>A p.E1486K (on ENST00000361203 / NM_001374722.1; = p.E1160K on NM_015548.5) | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- NADK | c.974C>T p.T325M | Missense Mutation (SNP) | VAF 50/292 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PROS1 | c.2006T>A p.V669D | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- UBL7 | c.401T>G p.L134R | Missense Mutation (SNP) | VAF 75/334 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZC2HC1C | c.470C>G p.T157S | Missense Mutation (SNP) | VAF 97/648 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
